Gene-level copy-number profile of tumor specimen TCGA-FR-A3YN-06A from TCGA case TCGA-FR-A3YN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 50.8 years (18,546 days).
Specimen TCGA-FR-A3YN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.d678ed71-469c-4fc8-81e2-eb60154e9c53.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FR-A3YN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9024449d-1b8c-4f33-b948-0e23d3192b3c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 11,158; copy number 3: 26,379; copy number 4: 6,729; copy number 5: 7,255; copy number 6: 8,288.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FR-A3YN-06A-11D-A238-01): tumor purity 0.73, ploidy 3.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,995,301, 2 genes: CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
